Surgical pathology report (de-identified scan), TCGA case TCGA-TS-A7P8, project TCGA-MESO (Mesothelioma), tissue source site University of Pennsylvania, specimen TCGA-TS-A7P8-01A (Primary Tumor).

[page 1 of 5]
Age: [REDACTED] years Sex: Male

Date Printed:
Date Collected
Date Received:
Accession No: [REDACTED]
Physician:
Copy to:

Surgical Pathology Report

CCF ICD-O-3
Mesothelioma, biphasic NOS
path 9053/3
Mesothelioma, epithelioid NOS
9052/3
Site @ Pleura ^{NOS} C38.4
9/24/13

Clinical Information

year old male with mesothelioma; Bronchoscopy, Left Thoracotomy & PDT

Final Diagnosis

1. RIB:

Benign lamellar bone with trilinear bone marrow formation present, no tumor seen.

2. ANTERIOR HILAR NODE:

Fragments of lymph node with presence of mesothelioma.

3. PERICARDIAL FAT:

Sections of lymph node, no tumor seen.

Fragments of fibrofatty soft tissue, no tumor seen.

Immunohistochemical stain confirms absence of tumor invasion into fat.

NOTE: Lymph node with cluster of 3 cells positive for CK7, not apparent on H&E section, suggestive of minute metastasis.

4. LEVEL 7:

Sections of lymph node, no tumor seen.

5. LEVEL 6:

Sections of lymph node, no tumor seen.

6. LEVEL 5:

Fibrofatty soft tissue with small amount of lymphoid tissue, no tumor seen.

7. LEVEL 9:

Sections of lymph node, no tumor seen.

Sections of soft tissue with presence of mesothelioma.

8. LEVEL 8:

Sections of lymph node, no tumor seen.

9. PHRENIC NODE:

Sections of lymph node, no tumor seen.

10. POSTERIOR INTERCOSTAL:

Lymph node with presence of mesothelioma.

Name: [REDACTED]

MRN: [REDACTED]

[page 2 of 5]
Name: [REDACTED]
MRN: [REDACTED]
DOB: [REDACTED] Age: [REDACTED] years Sex: Male
Loc.: [REDACTED]

Date Printed: [REDACTED]
Date Collected: [REDACTED]
Date Received: [REDACTED]
Accession No: [REDACTED]
Physician: [REDACTED]
Copy to: [REDACTED]

S u r g i c a l P a t h o l o g y R e p o r t

11. PLEURA:

Sections of soft tissue with extensive presence of mesothelioma.
Lung parenchyma with surrounding dense areas of mesothelioma and a large tongue of tumor growing into the lung
parenchyma with alveolar tissue surrounding the tip of the tumor extension.
Surrounding skeletal muscle, no tumor seen within skeletal muscle

The case material was reviewed and the report verified by: [REDACTED] (Electronic signature)
Verification Date: [REDACTED]

Note

Mesothelioma

Site:
Left

Histologic Type
Epithelioid mesothelioma

Margins
Cannot be assessed

Lymph nodes
Specify: Number examined: 8 anatomic sites
Number involved: 2 anatomic sites (see description of #3)

Pathologic Staging (pTx N1 Mx)

Gross Description

The case is received in 11 containers, each labeled with the patient's name and medical record number.

Specimen #1 is received in formalin, designated as "Rib" and consists of a 1.8 x 1.4 x 0.7 cm ragged and irregular fragment of trabeculated bone, which is serially sectioned and submitted entirely in cassette 1A following decalcification.

Specimen #2 is received in formalin, designated as "Anterior Hilar Node" and consists of a 1.1 x 0.8 x 0.5 cm gray-black, nodular soft tissue fragment, which is bisected and submitted entirely in cassette 2A.

Name: [REDACTED]
MRN: [REDACTED]

[page 3 of 5]
Name: [REDACTED]
MRN: [REDACTED]
DOB: [REDACTED] Age: [REDACTED] years Sex: Male
Loc.: [REDACTED]

Date Printed:
Date Collected :
Date Received:
Accession No: [REDACTED]
Physician:
Copy to:

S u r g i c a l P a t h o l o g y R e p o r t

Specimen #3 is received in formalin, designated as "Pericardial Fat" and consists of a 5.3 x 2.7 x 0.9 cm irregular fragment of tan-yellow, lobulated adipose tissue. Sectioning reveals a 0.3 cm tan-pink, possible lymph node (cassette 3A). No discrete masses or lesions are identified. The specimen is submitted entirely in cassettes 3A through 3D.

Specimen #4 is received in formalin, designated as "Level 7" and consists of three tan-gray, irregular to nodular soft tissue fragments measuring 0.6, 1.7 and 1.8 cm in greatest dimension. The largest fragment is bisected and submitted entirely in cassette 4A, and the remainder of the irregular soft tissue fragments are submitted in toto in cassette 4B.

Specimen #5 is received in formalin, designated as "Level 6" and consists of a 1.2 x 0.6 x 0.6 cm gray-black, nodular soft tissue fragment, which is bisected to reveal gray-black, dense cut surfaces. The specimen is submitted entirely in cassette 5A.

Specimen #6 is received in formalin, designated as "Level 5" and consists of a 1.5 x 0.7 x 0.7 cm gray-black to tan-yellow, nodular soft tissue fragment, which is bisected to reveal tan-yellow, dense cut surfaces. The specimen is submitted entirely in cassette 6A.

Specimen #7 is received in formalin, designated as "Level 9" and consists of three gray-black to tan-yellow, irregular soft tissue fragments measuring 0.4, 0.8 and 0.9 cm in greatest dimension. The specimen is submitted in toto in cassette 7A.

Specimen #8 is received in formalin, designated as "Level 8" and consists of a 1.7 x 1.0 x 0.7 cm tan-white, firm, nodular soft tissue fragment, which is bisected to reveal tan-white, firm cut surfaces. The specimen is submitted entirely in cassette 8A.

Specimen #9 is received in formalin, designated as "Phrenic Node" and consists of a 1.3 x 0.9 x 0.3 cm gray-black, irregular soft tissue fragment, which is submitted in toto in cassette 9A.

Specimen #10 is received in formalin, designated as "Posterior Intercostal" and consists of multiple tan-yellow to gray-black, regular soft tissue fragments measuring 2.5 x 1.5 x 0.4 cm in aggregate. The specimen is submitted in toto in cassette 10A.

Specimen #11 is received in formalin, designated as "Pleura" and consists of a 600.3 g, 24.5 x 20.6 x 9.3 cm aggregate of multiple ragged and irregular fragments of tan-yellow to tan-gray, rubbery soft tissue, grossly consistent with portions of parietal pleura. Each fragment is diffusely covered by tan, firm, thickened nodules. Sectioning reveals diffusely tan-white, firm nodular areas which appear to involve the attached adipose tissue and grossly abuts portions of red-brown muscle. There are possible grossly positive lymph nodes identified (cassette 11C and 11D). Representative sections are submitted in cassettes 11A through 11G.

Dictated by:

Name: [REDACTED]
MRN: [REDACTED]

[page 4 of 5]
Name: [REDACTED]
MRN: [REDACTED]
Age: [REDACTED] years Sex: Male
Loc.: [REDACTED]

Date Printed:
Date Collected:
Date Received:
Accession No. [REDACTED]
Physician:
Copy to:

S u r g i c a l P a t h o l o g y R e p o r t

Pathologist(s)

Name: [REDACTED]
MRN: [REDACTED]

*Pw TSS dx discrepancy from
TCOA specimen is biphasic,
not epithelial. BCR*

Page 4 of 4

[page 5 of 5]
TCGA Pathologic Diagnosis Discrepancy Form 4.05

Study Subject ID:		Person ID:	N/A
Study/Site:	TCGA Mesothelioma -	Age:	N/A
Event:	PathDiscrepancy	Date of Birth:	
Interviewer:		Sex:	M

Tumor Identifier Provided on Initial Case Quality Control Form

Provide the tumor identifier documented on the initial case quality control form for this case.

Pathologic Diagnosis Provided on Initial Pathology Report

epithelioid Provide the diagnosis/ histologic subtype(s) documented on the initial pathology report for this case. If the histology for this case is mixed, provide all listed subtypes.

Histologic features of the sample provided for TCGA, as reflected on the CQCF

biphasic Provide the histologic features selected on the TCGA Case Quality Control Form completed for this case.

Discrepancy between Pathology Report and Case Quality Control Form

Provide the reason for the discrepancy between the pathology report and the TCGA Case Quality Control Form

Submitted specimen is biphasic (epithelioid & sarcomatoid); the frozen specimen for clinical diagnosis is epithelioid and indicated as such in the pathology report.

Provide a reason describing why the diagnosis on the initial pathology report for this case is not consistent with the diagnosis selected on the TCGA Case Quality Control Form.

Name of TSS Reviewing Pathologist or Biorepository Director

Provide the name of the pathologist who reviewed this case for TCGA.

Source: NCI Genomic Data Commons file 52fb509e-9910-4908-8675-ddbf12d4aa18 (TCGA-TS-A7P8.9B0C36C1-5A4F-4A97-8EF0-0D8C6D812D0A.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).